Somatic mutation profile of tumor specimen MP2PRT-PAPIGD-TMP1-A (aliquot MP2PRT-PAPIGD-TMP1-A-1-0-D-A83A-36) from MP2PRT case MP2PRT-PAPIGD, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.1 years (1,876 days).
Specimen MP2PRT-PAPIGD-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8c7f529f-f815-43cb-a1a6-aafaa30a506e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPIGD-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPIGD-NB1-A-1-0-D-A83A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/653d7458-f4af-4328-a1ce-3bbf22a2e347

The open-access MAF lists 33 somatic variants for this specimen: 30 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Nonsense Mutation 3, Silent 2, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRV1 | c.3521G>A p.G1174E | Missense Mutation (SNP) | VAF 97/371 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs776576004, COSV67996312; called by muse, mutect2, varscan2
- ATF7IP | c.2386C>T p.Q796* | Nonsense Mutation (SNP) | VAF 16/430 reads (4%) | catalogued as COSV99662218; called by muse, mutect2
- DCC | c.3232C>G p.P1078A | Missense Mutation (SNP) | VAF 105/237 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV71431361; called by muse, mutect2, varscan2
- DLX5 | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 161/378 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.094); catalogued as rs758348857, COSV56032081; called by muse, mutect2, varscan2
- EIF4EBP1 | c.76G>A p.G26S | Missense Mutation (SNP) | VAF 40/732 reads (5%) | SIFT tolerated (0.4); PolyPhen benign (0.116); catalogued as rs968128057; called by muse, mutect2
- FGD1 | c.1867G>A p.V623M | Missense Mutation (SNP) | VAF 84/320 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs754355805, COSV64309156; called by muse, mutect2, varscan2
- GABRA1 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 103/242 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1457242041, COSV50098975; called by muse, mutect2, varscan2
- GPR149 | c.1885G>T p.E629* | Nonsense Mutation (SNP) | VAF 162/353 reads (46%) | catalogued as COSV67669786; called by muse, mutect2, varscan2
- HMCN1 | c.6730C>T p.R2244* | Nonsense Mutation (SNP) | VAF 98/252 reads (39%) | catalogued as rs373249075, COSV54909354; called by muse, varscan2
- MITF | c.214C>T p.R72C | Missense Mutation (SNP) | VAF 175/420 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1478130504, COSV58881846; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MSL3 | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 122/312 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1455131872, COSV56493209; called by muse, mutect2, varscan2
- NTM | c.367C>A p.P123T | Missense Mutation (SNP) | VAF 169/349 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as COSV100866773; called by muse, mutect2, varscan2
- PRDM5 | c.1231G>A p.A411T | Missense Mutation (SNP) | VAF 113/270 reads (42%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.984); catalogued as COSV53366595; called by muse, mutect2, varscan2
- RTL5 | c.139C>T p.R47W | Missense Mutation (SNP) | VAF 42/630 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.925); catalogued as COSV65454369; called by muse, mutect2
- SHB | c.1237G>A p.G413R | Missense Mutation (SNP) | VAF 113/269 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780018157, COSV100891849; called by muse, mutect2, varscan2
- SPANXN2 | c.241G>A p.V81I | Missense Mutation (SNP) | VAF 40/768 reads (5%) | SIFT tolerated (0.85); PolyPhen benign (0.1); catalogued as rs782507654, COSV65127843, COSV65127901; called by muse, mutect2
- TMPRSS3 | c.1172C>T p.T391M | Missense Mutation (SNP) | VAF 95/307 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as rs145766262, COSV52308871; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WNT2B | c.755G>T p.W252L (on ENST00000369684 / NM_024494.3; = p.W233L on NM_004185.4) | Missense Mutation (SNP) | VAF 163/414 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56677550; called by muse, mutect2, varscan2
- AC242842.3 | c.107G>T p.R36I | Missense Mutation (SNP) | VAF 101/688 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- DYRK4 | c.1237C>G p.Q413E | Missense Mutation (SNP) | VAF 118/372 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- ETV6 | c.775dup p.R259Pfs*41 | Frame Shift Ins (INS) | VAF 233/553 reads (42%) | called by mutect2, pindel, varscan2
- GLUD2 | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 250/659 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GRIN2A | c.1409C>G p.T470S | Missense Mutation (SNP) | VAF 32/676 reads (5%) | SIFT tolerated (0.44); PolyPhen benign (0.099); called by muse, mutect2
- PCYT1B | c.526G>T p.A176S | Missense Mutation (SNP) | VAF 88/355 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- QRICH2 | c.3487G>C p.E1163Q | Missense Mutation (SNP) | VAF 21/414 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2
- RASGEF1B | c.238G>C p.E80Q | Missense Mutation (SNP) | VAF 20/434 reads (5%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.015); called by muse, mutect2
- RRAGB | c.606T>G p.F202L (on ENST00000262850 / NM_016656.4; = p.F174L on NM_006064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 87/237 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- SYN1 | c.1490G>C p.G497A | Missense Mutation (SNP) | VAF 22/486 reads (5%) | SIFT tolerated (0.48); PolyPhen benign (0.066); called by muse, mutect2
- TMEM143 | c.163C>G p.R55G | Missense Mutation (SNP) | VAF 224/511 reads (44%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- TMEM178B | c.391G>C p.E131Q | Missense Mutation (SNP) | VAF 58/224 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PCNT | c.5406G>C p.L1802= | Silent (SNP) | VAF 129/461 reads (28%) | called by muse, mutect2, varscan2
- ZNF582 | c.117C>T p.Y39= | Silent (SNP) | VAF 148/332 reads (45%) | called by muse, varscan2
- XIRP2 | c.*939C>T | 3'UTR (SNP) | VAF 22/283 reads (8%) | catalogued as rs756155715, COSV54714956; called by muse, mutect2
